Somatic mutation profile of tumor specimen MP2PRT-PAUGEX-TMP1-A (aliquot MP2PRT-PAUGEX-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUGEX, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,289 days).
Specimen MP2PRT-PAUGEX-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58c008ab-eba5-4015-8b63-d81736aa21b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGEX-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGEX-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bf71a22-8453-4922-a2ac-8538d92d811a

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 74/201 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADAMTS9 | c.5366T>C p.F1789S | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1301745811; called by muse, mutect2, varscan2
- FGF4 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 24/569 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.284); catalogued as COSV99395246; called by muse, mutect2
- FHOD3 | c.3577C>G p.Q1193E (on ENST00000359247 / NM_001281739.3; = p.Q1210E on NM_025135.5) | Missense Mutation (SNP) | VAF 66/291 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs758359909; called by muse, mutect2, varscan2
- IGHE | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.535); catalogued as rs375858136; called by muse, mutect2, varscan2
- OR5B3 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs372384649; called by muse, mutect2, varscan2
- UNC45B | c.1127G>A p.R376H | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs779255426, COSV52098471; called by muse, mutect2, varscan2
- ARID2 | c.3292G>T p.V1098F | Missense Mutation (SNP) | VAF 101/262 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ETV6 | c.312_313insGA p.R105Dfs*18 | Frame Shift Ins (INS) | VAF 24/219 reads (11%) | called by mutect2, pindel*
- PIGO | c.1192A>C p.N398H | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.17); called by muse, mutect2
- TTN | c.42787G>C p.D14263H (on ENST00000591111; = p.D6839H on NM_003319.4) | Missense Mutation (SNP) | VAF 56/165 reads (34%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAM1 | c.777C>T p.D259= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as rs372281288; called by muse, mutect2, varscan2
- WNK2 | c.2106G>A p.P702= | Silent (SNP) | VAF 193/522 reads (37%) | catalogued as rs767702398; called by muse, mutect2, varscan2
- FHOD3 | c.1197-5496C>T | Intron (SNP) | VAF 77/275 reads (28%) | catalogued as rs1297444072; called by muse, mutect2, varscan2
